Somatic mutation profile of tumor specimen MP2PRT-PAUFPW-TMP1-A (aliquot MP2PRT-PAUFPW-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUFPW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,145 days).
Specimen MP2PRT-PAUFPW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88af12e7-71cd-4922-a781-8135fd72eeba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFPW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFPW-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c94b36ce-e4ba-4ea3-b00b-4826ed002cb1

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.213T>G p.F71L | Missense Mutation (SNP) | VAF 55/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1555267558, COSV61005635, COSV61011607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 52/388 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- CCDC57 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 115/584 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs531085389, COSV58934529; called by muse, mutect2, varscan2
- OTOA | c.1138G>A p.V380I (on ENST00000286149; = p.V366I on NM_144672.4) | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs764772897, COSV53750352; called by muse, mutect2, varscan2
- TMEM150C | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 66/791 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs765257134, COSV101497308; called by muse, mutect2
- GLIS3 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 78/928 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- HECTD1 | c.2684A>C p.N895T | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- JUNB | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 125/764 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PKHD1L1 | c.9163G>C p.V3055L | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2
- SLIT2 | c.4099T>G p.C1367G | Missense Mutation (SNP) | VAF 36/740 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- PLBD2 | c.1365G>A p.G455= | Silent (SNP) | VAF 110/377 reads (29%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.3000C>T p.T1000= | Silent (SNP) | VAF 174/427 reads (41%) | catalogued as rs775336208, COSV99691942; called by muse, mutect2, varscan2
- ROBO1 | c.486G>A p.S162= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as rs750389835, COSV71396055; called by muse, mutect2, varscan2
